MMRF case MMRF_1768 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/86a892e1-0cf8-4818-87f6-9d3b1bc97468

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.4 years (23,507 days); ISS stage: I; Days to last known disease status: 478 days (1.3 years); Days to last follow up: 478 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 148 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 148 days; Days to treatment end: 148 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 149 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 0): M Protein 2.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 4.32 g/L; Immunoglobulin A 28.6 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.35 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 44 g/L; Total Protein 8.4 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 0.22 mg/dL.
- Day 77 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.949 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 6.98 g/L; Immunoglobulin A 2.41 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.03 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.23 mmol/L.
- Day 171 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.036 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.48 mg/dL; Immunoglobulin G 6.06 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 4.7 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.14 ×10⁹/L; Platelets 319 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 5.89 mmol/L.
- Day 245 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.383 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.506 mg/dL; Immunoglobulin G 6.54 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 4.68 mmol/L.
- Day 350 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.947 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 8.39 g/L; Immunoglobulin A 2.52 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 2.24 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 4.35 mmol/L.
- Day 382: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Hemoglobin 7.44 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.38 mmol/L; Albumin 48 g/L; Glucose 5.01 mmol/L.
- Day 478 (ECOG 0): M Protein 0 g/dL; Hemoglobin 7.5 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 3.8 mmol/L.

Other clinical attributes
- Day -14: Weight: 80 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Bladder Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1768_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_1768_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
